Somatic mutation profile of tumor specimen MP2PRT-PASKPJ-TMP1-A (aliquot MP2PRT-PASKPJ-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASKPJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,594 days).
Specimen MP2PRT-PASKPJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f766e5c4-e0aa-4cb3-8636-9404e1b9a9be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKPJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKPJ-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8758cd58-21bc-47e5-8678-d3dc5add1432

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 3'Flank 1, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 82/270 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs778780969, COSV52215929; called by muse, mutect2, varscan2
- AK5 | c.1291C>T p.R431C (on ENST00000354567 / NM_174858.3; = p.R405C on NM_012093.4) | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs773232937; called by muse, mutect2, varscan2
- ARID4B | c.2657G>T p.R886I | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99935595; called by muse, mutect2
- CYP4F12 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61174440; called by muse, mutect2
- IGHV1-46 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1337425972; called by muse, varscan2
- MIS18BP1 | c.3193_3195del p.H1065del | In Frame Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs758179544; called by mutect2, pindel, varscan2
- OR52A1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100200486; called by muse, mutect2
- ZMYND15 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 75/343 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs149610977; called by muse, mutect2, varscan2
- C10orf90 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CCDC184 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 152/512 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEA6 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 137/214 reads (64%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- TRAV8-3 | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TRIR | c.199dup p.E67Gfs*48 | Frame Shift Ins (INS) | VAF 231/738 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.408G>A p.Q136= | Silent (SNP) | VAF 124/384 reads (32%) | called by muse, mutect2, varscan2
- ADGRD2 | c.798C>T p.P266= | Silent (SNP) | VAF 52/701 reads (7%) | called by muse, mutect2
- CCDC180 | c.3159C>T p.V1053= | Silent (SNP) | VAF 22/258 reads (9%) | called by muse, mutect2
- IGHV1-45 | chr14:106511116 ins TCTCGG | 5'Flank (INS) | VAF 10/37 reads (27%) | called by pindel, varscan2
- TRBV30 | chr7:142812585 ins ATCCCCCGT | 3'Flank (INS) | VAF 28/126 reads (22%) | called by mutect2, pindel, varscan2
